Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A45G, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A45G-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (21 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, TWO FOCI (0.1 CM AND 2.5 CM), RIGHT LOBE.
- B. LARGEST: ENCAPSULATED FOLLICULAR VARIANT (2.5 cm) WITH FOCAL CAPSULAR AND ANGIOLYMPHATIC INVASION *≥ 99% pw TSS.*
- C. BOTH FOCI CONFINED TO THYROID.
- D. PATHOLOGIC STAGE: pT2N1a.
- E. NODULAR THYROID HYPERPLASIA.
- F. ONE LEFT INFERIOR NORMOCELLULAR PARATHYROID.

PART 2: LYMPH NODES, CENTRAL COMPARTMENT, SELECTIVE NECK DISSECTION -

- A. METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF SEVEN LYMPH NODES (4/7).
- B. NO EXTRANODAL EXTENSION.
- C. SPECIMEN ENTIRELY SUBMITTED FOR HISTOLOGIC EVALUATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 2.5 cm
HISTOLOGIC TYPE: Papillary carcinoma, encapsulated follicular variant
PRIMARY TUMOR (pT): pT2
REGIONAL LYMPH NODES (pN): pN1a

Number of regional lymph nodes examined: 7
Number of regional lymph nodes involved: 4

EXTRANODAL EXTENSION: Not identified
DISTANT METASTASIS (pM): Not applicable
EXTRATHYROIDAL EXTENSION: Not identified
MARGINS: Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: Other: Nodular Thyroid Hyperplasia

ICD-0-3

Carcinoma, papillary, follicular variant. 8340/3

Site: Thyroid, NOS C73.9

hw
9/29/12

Source: NCI Genomic Data Commons file 2b625df4-026b-485f-8a93-400df111eba2 (TCGA-BJ-A45G.4B23A4BB-14FC-4A52-A148-0739020C65AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).